Somatic mutation profile of tumor specimen TCGA-DU-7298-01A (aliquot TCGA-DU-7298-01A-11D-2024-08) from TCGA case TCGA-DU-7298, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 38.9 years (14,205 days).
Specimen TCGA-DU-7298-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7b6530b-e545-4997-b691-28c2df22cf55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7298-10A (Blood Derived Normal), aliquot TCGA-DU-7298-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f3eb6a8-692b-44a0-927c-9c1ee8a92249

The open-access MAF lists 35 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 23, Silent 6, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 8/40 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.672G>A p.E224= | Splice Region (SNP) | VAF 13/25 reads (52%) | catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.578A>C p.H193P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACIN1 | c.62G>C p.R21P | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.689); catalogued as COSV52972892; called by muse, mutect2
- ATRX | c.3003del p.V1002* | Frame Shift Del (DEL) | VAF 54/162 reads (33%) | catalogued as COSV64877278; called by mutect2, pindel, varscan2
- CAD | c.3485C>T p.S1162L | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53023273; called by muse, mutect2, varscan2
- CNGA2 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV61702995, COSV61705058; called by muse, mutect2, varscan2
- CNOT10 | c.527A>G p.E176G | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV59389936; called by muse, mutect2, varscan2
- CPVL | c.426G>A p.W142* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as COSV55298795; called by muse, mutect2, varscan2
- CROCC | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs201480427, COSV65009797; called by muse, varscan2
- CRYBG2 | c.4707G>A p.W1569* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as rs1292852085, COSV57483508; called by muse, mutect2, varscan2
- DCDC1 | c.755A>G p.D252G | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); catalogued as rs1202381469, COSV60833292; called by muse, mutect2, varscan2
- EIF4B | c.1387A>G p.K463E | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV50401535; called by muse, mutect2, varscan2
- EPHA5 | c.976A>G p.S326G | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as rs1176279136, COSV56629190, COSV56644684; called by muse, mutect2
- FBXO47 | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65241074; called by muse, mutect2, varscan2
- HAVCR1 | c.184G>C p.V62L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV59397482; called by muse, mutect2, varscan2
- KIF13A | c.5414A>G p.Q1805R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52441899; called by muse, varscan2
- NFATC2 | c.2248G>A p.V750I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs1568969021, COSV65360039; called by muse, mutect2, varscan2
- NFKBIZ | c.1330G>T p.G444C | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58198953; called by muse, mutect2, varscan2
- OR5K2 | c.770T>C p.F257S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as COSV71143000, COSV71143106; called by muse, mutect2, varscan2
- SCIN | c.1304A>T p.Q435L (on ENST00000297029 / NM_001112706.3; = p.Q188L on NM_033128.3) | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.056); catalogued as COSV51688973; called by muse, mutect2, varscan2
- SELPLG | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as rs1055829508, COSV57311275; called by muse, mutect2, varscan2
- SLC5A9 | c.1432G>C p.A478P | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52581859; called by muse, mutect2, varscan2
- SMTN | c.265A>G p.M89V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs757434939, COSV60774876; called by muse, mutect2
- TYW3 | c.269A>G p.K90R | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV63802389; called by muse, mutect2, varscan2
- XDH | c.2473C>T p.R825* | Nonsense Mutation (SNP) | VAF 43/148 reads (29%) | catalogued as rs748879270, CM118253, COSV101052117, COSV65146698; called by muse, mutect2, varscan2
- ZEB2 | c.1024G>C p.G342R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57950732; called by mutect2, varscan2
- RIPK1 | c.1074del p.W358Cfs*154 | Frame Shift Del (DEL) | VAF 45/161 reads (28%) | called by mutect2, pindel, varscan2
- ADAMTS19 | c.3183C>A p.G1061= | Silent (SNP) | VAF 70/183 reads (38%) | catalogued as COSV50731577; called by muse, mutect2, varscan2
- GLOD4 | c.15A>G p.R5= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs1361175093, COSV56752368; called by muse, mutect2, varscan2
- JPH4 | c.1302C>T p.S434= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs182379018; called by mutect2, varscan2
- NRK | c.2664C>T p.N888= | Silent (SNP) | VAF 55/150 reads (37%) | catalogued as rs762097483, COSV54589144; called by muse, mutect2, varscan2
- RAD50 | c.1947T>A p.I649= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV54747119; called by muse, mutect2, varscan2
- USH2A | c.1377T>G p.P459= | Silent (SNP) | VAF 43/154 reads (28%) | catalogued as COSV56323946; called by muse, mutect2, varscan2
